Somatic mutation profile of tumor specimen TCGA-BQ-5882-01A (aliquot TCGA-BQ-5882-01A-11D-1589-08) from TCGA case TCGA-BQ-5882, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 54.9 years (20,042 days).
Specimen TCGA-BQ-5882-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0734d78-5927-4432-8450-b4bd26e4b328.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BQ-5882-11A (Solid Tissue Normal), aliquot TCGA-BQ-5882-11A-01D-1589-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/216a3cf9-3219-4e50-bdd1-0f9d330fdde0

The open-access MAF lists 64 somatic variants for this specimen: 50 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 38, Silent 14, Nonsense Mutation 5, Frame Shift Ins 4, Splice Region 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC006059.2 | c.653A>C p.Q218P | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV59605837; called by muse, varscan2
- ACADL | c.415G>A p.G139S | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.174); catalogued as COSV52052230; called by muse, mutect2, varscan2
- ADAMTS7 | c.2165C>T p.A722V | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66306014; called by muse, mutect2, varscan2
- ALG10B | c.599T>C p.V200A | Missense Mutation (SNP) | VAF 135/417 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs773481194, COSV58142400; called by muse, mutect2, varscan2
- CCNI2 | c.551C>A p.S184* | Nonsense Mutation (SNP) | VAF 39/141 reads (28%) | catalogued as COSV66393961; called by muse, mutect2, varscan2
- CLPTM1 | c.1693G>A p.V565I | Missense Mutation (SNP) | VAF 90/232 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.053); catalogued as rs369873479; called by muse, mutect2, varscan2
- CYRIB | c.184G>T p.E62* | Nonsense Mutation (SNP) | VAF 51/142 reads (36%) | catalogued as COSV63118385, COSV63118394; called by muse, mutect2, varscan2
- DAP3 | c.284delinsAA p.S95Kfs*2 | Frame Shift Ins (INS) | VAF 64/225 reads (28%) | catalogued as COSV100546681; called by mutect2*, pindel, varscan2*
- DGKD | c.2311G>T p.G771C (on ENST00000264057 / NM_152879.3; = p.G727C on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51033798; called by muse, mutect2, varscan2
- EPC1 | c.827G>C p.G276A | Missense Mutation (SNP) | VAF 25/156 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV53923360; called by muse, mutect2, varscan2
- EPHB1 | c.437T>A p.F146Y | Missense Mutation (SNP) | VAF 98/198 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67654651; called by muse, mutect2, varscan2
- FBXO10 | c.1219C>A p.L407M | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.796); catalogued as COSV52831536; called by muse, mutect2, varscan2
- HEATR5B | c.2898T>A p.S966R | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.141); catalogued as COSV51849278; called by muse, mutect2, varscan2
- HTRA4 | c.41G>A p.C14Y | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.015); catalogued as COSV56758456; called by muse, mutect2, varscan2
- KIAA1217 | c.182G>T p.R61L | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775695112, COSV64601075; called by muse, mutect2, varscan2
- KLHDC8A | c.220G>A p.V74I | Missense Mutation (SNP) | VAF 48/157 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1237436388, COSV65678245; called by muse, mutect2, varscan2
- MED12L | c.2818A>G p.S940G | Missense Mutation (SNP) | VAF 111/214 reads (52%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.931); catalogued as COSV56369446; called by muse, mutect2, varscan2
- MET | c.887T>C p.L296P | Missense Mutation (SNP) | VAF 53/184 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59257174; called by muse, mutect2, varscan2
- MGAT5 | c.2165G>A p.R722K | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56094039; called by muse, mutect2
- NLRP2 | c.635A>T p.Y212F | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as COSV54752615; called by muse, mutect2, varscan2
- OR5V1 | c.475C>G p.H159D | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65826474; called by muse, mutect2, varscan2
- OR8H3 | c.781A>G p.K261E | Missense Mutation (SNP) | VAF 54/112 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV57907548; called by muse, mutect2, varscan2
- OSBPL5 | c.423C>G p.S141R | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.382); catalogued as COSV55139539; called by muse, mutect2, varscan2
- PCDHB16 | c.1673C>A p.S558* | Nonsense Mutation (SNP) | VAF 15/33 reads (45%) | catalogued as COSV53358134; called by muse, mutect2, varscan2
- PHF20L1 | c.788G>C p.R263T | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55189125; called by muse, mutect2, varscan2
- PLPPR3 | c.602A>G p.K201R | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.718); catalogued as rs1275687647, COSV62458741; called by muse, mutect2, varscan2
- PROSER1 | c.651T>A p.Y217* | Nonsense Mutation (SNP) | VAF 64/131 reads (49%) | catalogued as COSV61486341; called by muse, mutect2, varscan2
- QRICH2 | c.2275C>T p.Q759* | Nonsense Mutation (SNP) | VAF 68/195 reads (35%) | catalogued as COSV53151098; called by muse, mutect2, varscan2
- RIMS1 | c.4726T>G p.Y1576D | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53440404; called by muse, mutect2, varscan2
- RLF | c.1609G>A p.D537N | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.794); catalogued as COSV65650734; called by muse, mutect2, varscan2
- RPL3 | c.117G>T p.K39N | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as COSV53364698; called by muse, mutect2, varscan2
- SATB1 | c.1782A>T p.Q594H | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV58667686; called by muse, mutect2, varscan2
- SIPA1L3 | c.3101A>C p.K1034T | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.171); catalogued as COSV55909259; called by muse, mutect2, varscan2
- STAB1 | c.2701G>A p.V901I | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs569908210, COSV58732514; called by muse, mutect2, varscan2
- TAF4B | c.992G>A p.R331Q | Missense Mutation (SNP) | VAF 93/178 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1350198483, COSV52301338; called by muse, mutect2, varscan2
- TERT | c.3044G>T p.C1015F | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57200630; called by muse, mutect2, varscan2
- TRIM9 | c.1196A>G p.Q399R | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.482); catalogued as COSV53613052; called by muse, mutect2, varscan2
- UGGT1 | c.2697C>A p.I899= | Splice Region (SNP) | VAF 39/127 reads (31%) | catalogued as COSV52132700; called by muse, mutect2, varscan2
- UNC13D | c.611T>A p.M204K | Missense Mutation (SNP) | VAF 136/429 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as COSV52883101; called by muse, mutect2, varscan2
- WRN | c.1024G>A p.V342I | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs764559021, COSV53296416; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- YY2 | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 184/263 reads (70%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV63410760; called by muse, mutect2, varscan2
- ZBTB8OS | c.352T>G p.F118V | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs748022309, COSV59384772; called by muse, mutect2, varscan2
- ZNF607 | c.823C>A p.H275N | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV67696219; called by muse, mutect2, varscan2
- ZNF780B | c.2422C>T p.P808S | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs781502967, COSV55461965; called by muse, mutect2, varscan2
- AC006059.2 | c.661_662dup p.D221Efs*11 | Frame Shift Ins (INS) | VAF 24/72 reads (33%) | called by pindel, varscan2
- CSPG4 | c.209del p.P70Qfs*25 | Frame Shift Del (DEL) | VAF 4/14 reads (29%) | called by mutect2, pindel
- DAP3 | c.283dup p.S95Kfs*2 | Frame Shift Ins (INS) | VAF 56/163 reads (34%) | called by mutect2, varscan2
- EFCAB6 | c.987dup p.V330Cfs*19 | Frame Shift Ins (INS) | VAF 22/87 reads (25%) | called by mutect2, pindel, varscan2
- RBM17 | c.1103-4_1103-2del p.X368_splice | Splice Site (DEL) | VAF 114/253 reads (45%) | called by mutect2, pindel, varscan2
- TBC1D3L | c.1612C>A p.L538I | Missense Mutation (SNP) | VAF 47/281 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- ANLN | c.651T>C p.N217= | Silent (SNP) | VAF 44/135 reads (33%) | catalogued as COSV56074107; called by muse, mutect2, varscan2
- EARS2 | c.1347G>A p.V449= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV71942755; called by muse, mutect2, varscan2
- FMNL2 | c.1209T>A p.S403= | Silent (SNP) | VAF 31/94 reads (33%) | catalogued as COSV56490512; called by muse, mutect2, varscan2
- GCN1 | c.5415C>A p.I1805= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as COSV56104225; called by muse, mutect2, varscan2
- GPD2 | c.378C>T p.I126= | Silent (SNP) | VAF 70/250 reads (28%) | catalogued as COSV60090335; called by muse, mutect2, varscan2
- MED1 | c.942T>A p.S314= | Silent (SNP) | VAF 44/109 reads (40%) | catalogued as COSV56122502; called by muse, mutect2, varscan2
- MUC17 | c.6468T>C p.Y2156= | Silent (SNP) | VAF 112/344 reads (33%) | catalogued as COSV60280916; called by muse, mutect2
- PTPRZ1 | c.2431C>T p.L811= | Silent (SNP) | VAF 106/357 reads (30%) | catalogued as COSV66430931; called by muse, mutect2, varscan2
- RNF166 | c.498G>T p.V166= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as COSV57189300; called by muse, mutect2, varscan2
- SLC25A2 | c.117G>A p.T39= | Silent (SNP) | VAF 30/98 reads (31%) | called by muse, mutect2, varscan2
- TIPRL | c.645G>A p.T215= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as rs755900308, COSV63208399; called by muse, mutect2, varscan2
- TMEM53 | c.351C>A p.V117= | Silent (SNP) | VAF 24/43 reads (56%) | catalogued as COSV62404910; called by muse, mutect2, varscan2
- TTN | c.27369C>T p.G9123= (on ENST00000591111; = p.G8196= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 49/167 reads (29%) | catalogued as rs375083775; ClinVar: likely benign / uncertain significance; called by muse, varscan2
- ZNF646 | c.2034T>C p.A678= | Silent (SNP) | VAF 31/84 reads (37%) | catalogued as COSV56211588, COSV56215825; called by muse, mutect2, varscan2
